Somatic mutation profile of tumor specimen TCGA-CL-4957-01A (aliquot TCGA-CL-4957-01A-01D-1733-10) from TCGA case TCGA-CL-4957, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Age at diagnosis: 79.6 years (29,081 days).
Specimen TCGA-CL-4957-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42987375-301c-41e5-b299-5ada9e37f8f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CL-4957-10A (Blood Derived Normal), aliquot TCGA-CL-4957-10A-01D-1733-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f81cd69d-0b13-41e3-a1ad-2efdba2793d3

The open-access MAF lists 93 somatic variants for this specimen: 65 protein-altering or splice-affecting, 26 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 26, Nonsense Mutation 9, Frame Shift Ins 2, Intron 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3810T>A p.C1270* | Nonsense Mutation (SNP) | VAF 18/126 reads (14%) | catalogued as rs863225347, CM000125, CX995213, COSV57342456, COSV57383570; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 26/67 reads (39%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 86/142 reads (61%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 69/105 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARMC4 | c.1492G>A p.V498M | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV59466578; called by muse, mutect2, varscan2
- ATP1B4 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs573970199, COSV54313497; called by muse, mutect2, varscan2
- CADM2 | c.938T>A p.V313E (on ENST00000407528 / NM_001167674.2; = p.V315E on NM_153184.4) | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV67385011; called by muse, mutect2, varscan2
- CCDC136 | c.1430C>T p.T477M | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs774739139, COSV52796030; called by muse, mutect2, varscan2
- CD47 | c.478T>C p.F160L | Missense Mutation (SNP) | VAF 139/296 reads (47%) | SIFT tolerated (0.64); PolyPhen benign (0.272); catalogued as COSV62527554; called by muse, mutect2, varscan2
- COL6A3 | c.1630C>T p.R544W | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749113845, COSV55095447; called by muse, mutect2, varscan2
- DENND2C | c.1248C>A p.D416E (on ENST00000393274 / NM_001256404.2; = p.D359E on NM_198459.4) | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV67922420; called by muse, mutect2, varscan2
- DNAH5 | c.9351G>A p.W3117* | Nonsense Mutation (SNP) | VAF 6/72 reads (8%) | catalogued as COSV99446224; called by muse, mutect2
- DND1 | c.812_813del p.P271Rfs*47 | Frame Shift Del (DEL) | VAF 46/176 reads (26%) | catalogued as COSV56907792; called by mutect2, pindel, varscan2
- FAM133A | c.150T>G p.N50K | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV59076330; called by muse, mutect2, varscan2
- FAM47B | c.692G>T p.R231L | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.091); catalogued as COSV61452422, COSV61454499, COSV61454829; called by muse, mutect2, varscan2
- FGF13 | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 21/60 reads (35%) | catalogued as COSV59544093; called by muse, mutect2, varscan2
- GABRB1 | c.355C>A p.P119T | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV99780253, COSV99780562; called by muse, mutect2, varscan2
- GBF1 | c.2482G>A p.A828T (on ENST00000369983 / NM_001377137.1; = p.A827T on NM_004193.3) | Missense Mutation (SNP) | VAF 48/200 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as COSV100890361, COSV64148035; called by muse, mutect2, varscan2
- GJB6 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.017); catalogued as rs771412904, COSV53832392; called by muse, mutect2, varscan2
- GLIPR1 | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs150045391, COSV56991664; called by muse, mutect2, varscan2
- HSDL2 | c.660A>C p.K220N | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV52715711; called by muse, mutect2, varscan2
- IL19 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.132); catalogued as rs375138273, COSV54282763; called by muse, mutect2, varscan2
- ITPRIPL1 | c.1114C>T p.R372* (on ENST00000439118 / NM_001008949.3; = p.R380* on NM_178495.6) | Nonsense Mutation (SNP) | VAF 29/95 reads (31%) | catalogued as rs527931884, COSV63152850; called by muse, mutect2, varscan2
- KAT7 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 86/196 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.059); catalogued as rs199567018, COSV52013773; called by muse, mutect2, varscan2
- KIF13A | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 41/180 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV99434553; called by muse, mutect2, varscan2
- KIF4B | c.1955G>A p.R652H | Missense Mutation (SNP) | VAF 75/321 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as rs199820075, COSV101469192, COSV70526998; called by muse, mutect2, varscan2
- KLHL23 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as rs753904002, COSV55865523, COSV55870242; called by muse, mutect2, varscan2
- LAMB1 | c.3355G>T p.E1119* | Nonsense Mutation (SNP) | VAF 39/90 reads (43%) | catalogued as COSV55966689; called by muse, mutect2, varscan2
- LONRF3 | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as rs1399758638, COSV59154041; called by muse, varscan2
- LRP1B | c.12079G>T p.G4027* | Nonsense Mutation (SNP) | VAF 25/55 reads (45%) | catalogued as COSV67241272; called by muse, mutect2, varscan2
- LRRC30 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.353); catalogued as COSV67301639; called by muse, mutect2, varscan2
- LRRK1 | c.3363A>T p.Q1121H | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV52617026; called by muse, mutect2, varscan2
- MAGIX | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 19/235 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.581); catalogued as rs1389695304, COSV100891845; called by muse, mutect2
- MDM2 | c.700G>T p.V234L | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV50700324, COSV99254825; called by muse, mutect2, varscan2
- MME | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64708482; called by muse, varscan2
- MYOZ1 | c.694G>T p.E232* | Nonsense Mutation (SNP) | VAF 21/149 reads (14%) | catalogued as COSV100831804; called by muse, mutect2, varscan2
- NBEA | c.3989G>A p.R1330H | Missense Mutation (SNP) | VAF 25/235 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59773467; called by muse, mutect2, varscan2
- OR1G1 | c.860C>A p.P287H | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61030342, COSV61030643; called by muse, mutect2, varscan2
- OR2B2 | c.836G>T p.G279V | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV57580026; called by muse, mutect2, varscan2
- OR6C6 | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.149); catalogued as rs77411445; called by muse, mutect2, varscan2
- OSBPL10 | c.1117G>C p.V373L | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs140791134; called by muse, mutect2, varscan2
- PENK | c.626G>T p.R209L | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59240213, COSV59242061; called by muse, mutect2, varscan2
- PLXND1 | c.2585G>A p.R862H | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs745841532, COSV60715509; called by muse, mutect2, varscan2
- RAF1 | c.1097G>T p.G366V | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52575688, COSV99312098; called by muse, mutect2, varscan2
- RIBC2 | c.490A>G p.N164D | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.71); catalogued as COSV100663058; called by muse, mutect2, varscan2
- RIMS1 | c.1592G>T p.S531I | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV99324864; called by muse, mutect2
- SCAF11 | c.1249C>G p.P417A | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV65477457; called by muse, mutect2
- SDK1 | c.4528C>T p.R1510W | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765428605, COSV67376333; called by muse, mutect2, varscan2
- SLC26A11 | c.496G>A p.G166S | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT tolerated (0.64); PolyPhen benign (0.159); catalogued as rs781211086, COSV58339420; called by muse, mutect2, varscan2
- SOX9 | c.1277_1278insGA p.H427Nfs*44 | Frame Shift Ins (INS) | VAF 26/136 reads (19%) | catalogued as COSV55425531; called by mutect2, pindel, varscan2
- SPRY3 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 119/392 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs779201129, COSV57142048; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPTA1 | c.4325C>A p.A1442E | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs1231530519, COSV100934539; called by muse, mutect2
- SRPX | c.289G>A p.G97S | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100655943, COSV59437281; called by muse, mutect2, varscan2
- TBCK | c.108C>G p.I36M | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749173215, COSV56757970; called by muse, mutect2, varscan2
- TNRC18 | c.6980C>T p.A2327V | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as COSV60308207; called by muse, mutect2, varscan2
- TNRC6A | c.438A>C p.K146N | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV59366762; called by muse, mutect2, varscan2
- VAX2 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs782753663, COSV52266386; called by muse, mutect2, varscan2
- ZNF157 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.175); catalogued as COSV65659184, COSV65659364; called by muse, mutect2
- ZNF568 | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771053654, COSV61740892, COSV61741839; called by muse, mutect2, varscan2
- ZNF804A | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56455870; called by muse, varscan2
- ZNF804B | c.832G>T p.E278* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV60817557, COSV60835590; called by muse, mutect2, varscan2
- AMER1 | c.1091_1101del p.T364Rfs*10 | Frame Shift Del (DEL) | VAF 55/194 reads (28%) | called by mutect2, pindel, varscan2
- NIBAN1 | c.1864T>G p.S622A | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2
- SYNRG | c.1961C>T p.T654I | Missense Mutation (SNP) | VAF 69/132 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ZSWIM2 | c.1377_1380dup p.A461Rfs*4 | Frame Shift Ins (INS) | VAF 12/118 reads (10%) | called by mutect2, pindel
- ADAMTS14 | c.549C>A p.T183= | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as COSV64603622; called by muse, mutect2, varscan2
- ARHGAP4 | c.330G>A p.T110= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as COSV63132744; called by muse, varscan2
- CCDC178 | c.972A>G p.E324= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as COSV55781207; called by muse, mutect2, varscan2
- CCER1 | c.15C>T p.L5= | Silent (SNP) | VAF 24/106 reads (23%) | catalogued as rs748954628, COSV62647470; called by muse, mutect2, varscan2
- CHD9 | c.6000C>T p.N2000= | Silent (SNP) | VAF 28/160 reads (18%) | catalogued as COSV54612243; called by muse, mutect2, varscan2
- CNTNAP2 | c.1038C>T p.N346= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as rs904267244, COSV62180746, COSV62180753; called by muse, mutect2, varscan2
- DNAH10 | c.11643C>T p.Y3881= (on ENST00000409039; = p.Y3820= on NM_207437.3) | Silent (SNP) | VAF 148/327 reads (45%) | catalogued as rs369302336; called by muse, mutect2, varscan2
- FOSL2 | c.174G>A p.Q58= | Silent (SNP) | VAF 86/186 reads (46%) | catalogued as COSV53104898; called by muse, mutect2, varscan2
- GRIK3 | c.111G>T p.R37= | Silent (SNP) | VAF 25/49 reads (51%) | catalogued as COSV100901501; called by muse, mutect2, varscan2
- ITGA11 | c.2454C>T p.S818= | Silent (SNP) | VAF 32/137 reads (23%) | catalogued as rs376522259; called by muse, mutect2, varscan2
- ITIH1 | c.1845G>A p.A615= | Silent (SNP) | VAF 71/148 reads (48%) | catalogued as rs535754406, COSV56256279; called by muse, mutect2, varscan2
- LCAT | c.600C>T p.F200= | Silent (SNP) | VAF 48/103 reads (47%) | catalogued as rs753143565, COSV50453115; called by muse, mutect2, varscan2
- LHX3 | c.1128G>A p.G376= (on ENST00000371748 / NM_178138.6; = p.G381= on NM_014564.5) | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV65582353; called by muse, mutect2, varscan2
- LY6K | c.246G>A p.A82= | Silent (SNP) | VAF 35/129 reads (27%) | catalogued as rs782387825, COSV52832165; called by muse, mutect2, varscan2
- MACF1 | c.7995C>T p.S2665= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as rs756390211, COSV99242201; called by mutect2, varscan2
- MRPL42 | c.406C>T p.L136= | Silent (SNP) | VAF 146/288 reads (51%) | catalogued as COSV62356420; called by muse, mutect2, varscan2
- OPHN1 | c.1770G>A p.T590= | Silent (SNP) | VAF 58/138 reads (42%) | catalogued as rs760485744, COSV100830259; called by muse, mutect2, varscan2
- PDZRN4 | c.2541C>T p.A847= (on ENST00000402685 / NM_001164595.2; = p.A589= on NM_013377.4) | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs1471964882, COSV100113875; called by muse, mutect2, varscan2
- RADX | c.420G>A p.E140= | Silent (SNP) | VAF 49/121 reads (40%) | catalogued as rs1264966339, COSV65319141; called by muse, mutect2, varscan2
- RHBDF2 | c.102C>T p.P34= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as rs751186227, COSV57421237; called by muse, mutect2, varscan2
- SARM1 | c.1722C>T p.S574= | Silent (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- TM6SF2 | c.936G>A p.S312= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs1260313688, COSV52269262; called by muse, mutect2, varscan2
- TMEM131 | c.4728T>G p.T1576= | Silent (SNP) | VAF 81/164 reads (49%) | catalogued as COSV51779268; called by muse, mutect2, varscan2
- TRIM3 | c.786C>A p.G262= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as COSV61984448; called by muse, mutect2, varscan2
- TRRAP | c.6999G>A p.T2333= (on ENST00000359863 / NM_001244580.1; = p.T2315= on NM_003496.3) | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as COSV62847650; called by muse, mutect2, varscan2
- ZNF618 | c.729G>A p.P243= (on ENST00000374126 / NM_001318042.2; = p.P211= on NM_133374.2) | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs757394566, COSV55923933; called by muse, mutect2
- MASP1 | c.1303+5576G>A | Intron (SNP) | VAF 22/121 reads (18%) | catalogued as rs754733542, COSV56225033; called by muse, mutect2, varscan2
- TMPRSS11F | c.1015+1596T>G | Intron (SNP) | VAF 40/204 reads (20%) | catalogued as COSV100678268; called by muse, mutect2, varscan2
